Somatic mutation profile of tumor specimen ALCH-B28A-TTP1-A (aliquot ALCH-B28A-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B28A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 85.6 years (31,282 days).
Specimen ALCH-B28A-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33e176dc-1873-486a-b958-0ba0fb6872d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B28A-NB1-A (Blood Derived Normal), aliquot ALCH-B28A-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af1faa20-cdd6-49c3-a7dc-089719b26ef5

The open-access MAF lists 90 somatic variants for this specimen: 56 protein-altering or splice-affecting, 20 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 20, Intron 6, Frame Shift Del 5, Nonsense Mutation 4, 5'UTR 3, RNA 2, 3'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 134/533 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- AL713999.2 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 53/248 reads (21%) | catalogued as rs374944263; called by muse, mutect2, varscan2
- CACNA2D2 | c.2870G>A p.R957Q (on ENST00000479441 / NM_001174051.3; = p.R950Q on NM_006030.4) | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1333604942, COSV56568362; called by muse, mutect2, varscan2
- CFAP74 | c.3461G>A p.R1154H | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as rs1428077009; called by muse, mutect2, varscan2
- CNGB1 | c.3613C>T p.L1205F | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs765506955; called by muse, varscan2
- CYP4F3 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs774751788, COSV99657972; called by muse, mutect2, varscan2
- EGFR | c.2126A>G p.E709G | Missense Mutation (SNP) | VAF 125/521 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs397517085, COSV51765252, COSV51766584, COSV51772956; ClinVar: uncertain significance / drug response; called by muse, mutect2, varscan2
- FLG | c.4132G>C p.A1378P | Missense Mutation (SNP) | VAF 190/730 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs746029503; called by muse, mutect2, varscan2
- GMNC | c.59G>T p.C20F | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1322225445; called by muse, varscan2
- KRT15 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs769451472, COSV54182179; called by muse, mutect2, varscan2
- KRTAP4-4 | c.80A>G p.Q27R | Missense Mutation (SNP) | VAF 91/312 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs199889274; called by muse, mutect2, varscan2
- MUC12 | c.2251G>A p.V751I (on ENST00000379442; = p.V608I on NM_001164462.1) | Missense Mutation (SNP) | VAF 85/448 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.101); catalogued as rs573974174; called by muse, mutect2
- OBSCN | c.13501G>A p.A4501T | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as rs1377440396, COSV99470759; called by muse, mutect2, varscan2
- POTEF | c.550G>T p.G184W | Missense Mutation (SNP) | VAF 50/538 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100664708; called by muse, mutect2
- RAC1 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.995); catalogued as rs1305062442, COSV61824615; called by muse, mutect2, varscan2
- RGS12 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 65/302 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763944261; called by muse, mutect2, varscan2
- RGS5 | c.282G>A p.W94* | Nonsense Mutation (SNP) | VAF 152/518 reads (29%) | catalogued as COSV100009203, COSV100009402; called by muse, mutect2, varscan2
- SLIT3 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415877188, COSV60604140; called by muse, mutect2, varscan2
- TM2D1 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs751636109; called by muse, mutect2, varscan2
- TMPRSS15 | c.2723G>A p.R908K | Missense Mutation (SNP) | VAF 43/280 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as COSV53043816; called by muse, mutect2, varscan2
- ZC3H15 | c.1175C>T p.T392M | Missense Mutation (SNP) | VAF 66/315 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as rs753910679, COSV100552236; called by muse, mutect2, varscan2
- AC004832.3 | c.771T>G p.F257L | Missense Mutation (SNP) | VAF 119/507 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); called by mutect2, varscan2
- ANGPTL6 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AQR | c.232T>C p.W78R | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF4 | c.1077C>A p.S359R | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARRDC3 | c.783_784del p.E261Dfs*20 | Frame Shift Del (DEL) | VAF 126/486 reads (26%) | called by pindel, varscan2
- CCDC30 | c.1546C>A p.L516I (on ENST00000340612; = p.L473I on NM_001080850.3) | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CD163L1 | c.452C>G p.A151G | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEP128 | c.2498A>T p.K833M | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CEP170 | c.2207A>G p.K736R | Missense Mutation (SNP) | VAF 106/886 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, varscan2
- DMXL1 | c.620C>G p.T207S | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHB1 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FAM149A | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated, low confidence (0.52); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- FRG2C | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 46/425 reads (11%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FRY | c.5470G>C p.E1824Q | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- FST | c.993C>A p.D331E | Missense Mutation (SNP) | VAF 77/292 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HK2 | c.605A>T p.D202V | Missense Mutation (SNP) | VAF 159/567 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- HPSE | c.682A>T p.S228C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- JUN | c.316_326del p.E106Lfs*200 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | called by mutect2, pindel, varscan2
- KCND3 | c.888G>T p.R296S | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF12 | c.1133A>C p.K378T (on ENST00000640217; = p.K240T on NM_138424.1) | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LRP1B | c.11651G>T p.G3884V | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- LRP1B | c.1056G>C p.E352D | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- MUC16 | c.42111C>G p.Y14037* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2
- MYO1H | c.1128del p.N376Kfs*7 | Frame Shift Del (DEL) | VAF 29/148 reads (20%) | called by mutect2, pindel, varscan2
- NKD1 | c.557C>A p.T186N | Missense Mutation (SNP) | VAF 64/303 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- NOTCH1 | c.4837C>T p.Q1613* | Nonsense Mutation (SNP) | VAF 84/389 reads (22%) | called by muse, mutect2, varscan2
- NSMCE3 | c.154C>G p.R52G | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH18 | c.2618G>T p.S873I | Missense Mutation (SNP) | VAF 91/292 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- PTP4A3 | c.262G>T p.V88L | Missense Mutation (SNP) | VAF 74/261 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM10 | c.1887del p.A631Hfs*73 | Frame Shift Del (DEL) | VAF 71/158 reads (45%) | called by mutect2, pindel, varscan2
- SLC2A11 | c.439G>A p.G147R (on ENST00000345044 / NM_001024938.4; = p.G154R on NM_030807.5) | Missense Mutation (SNP) | VAF 99/326 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SMIM7 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- TADA1 | c.4del p.A2Rfs*4 | Frame Shift Del (DEL) | VAF 45/317 reads (14%) | called by mutect2, pindel, varscan2
- TCF20 | c.3270C>G p.Y1090* | Nonsense Mutation (SNP) | VAF 93/332 reads (28%) | called by muse, mutect2, varscan2
- TESPA1 | c.521A>T p.D174V (on ENST00000316577 / NM_001098815.3; = p.D36V on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/276 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ABCB5 | c.2385A>T p.T795= (on ENST00000404938 / NM_001163941.2; = p.T350= on NM_178559.6) | Silent (SNP) | VAF 39/168 reads (23%) | called by muse, mutect2, varscan2
- BEND3 | c.1053C>T p.S351= | Silent (SNP) | VAF 82/265 reads (31%) | catalogued as rs1271096225; called by muse, mutect2, varscan2
- CRACDL | c.768G>A p.T256= | Silent (SNP) | VAF 116/511 reads (23%) | called by muse, mutect2, varscan2
- EML2 | c.438C>T p.S146= | Silent (SNP) | VAF 110/273 reads (40%) | called by muse, mutect2, varscan2
- GMPPA | c.321C>G p.P107= | Silent (SNP) | VAF 81/283 reads (29%) | catalogued as COSV58009012; called by muse, mutect2, varscan2
- GPR78 | c.207C>T p.R69= | Silent (SNP) | VAF 44/176 reads (25%) | catalogued as rs764075847; called by muse, mutect2, varscan2
- INPPL1 | c.1809C>T p.F603= | Silent (SNP) | VAF 53/223 reads (24%) | catalogued as COSV53356120; called by muse, mutect2, varscan2
- KCNE4 | c.474G>A p.E158= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs1277552430; called by muse, mutect2, varscan2
- KCNT2 | c.2016A>G p.P672= | Silent (SNP) | VAF 39/178 reads (22%) | catalogued as rs1016053555; called by muse, mutect2, varscan2
- MED25 | c.1764G>A p.P588= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs758729127; called by muse, mutect2, varscan2
- PANK1 | c.396C>T p.A132= | Silent (SNP) | VAF 56/218 reads (26%) | catalogued as rs1281103246; called by muse, mutect2, varscan2
- PCDHB8 | c.666C>A p.P222= | Silent (SNP) | VAF 149/972 reads (15%) | catalogued as COSV99177163; called by muse, mutect2, varscan2
- PIBF1 | c.261A>G p.E87= | Silent (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- SPPL2B | c.990C>T p.I330= | Silent (SNP) | VAF 40/175 reads (23%) | catalogued as rs574604961; called by muse, mutect2, varscan2
- TACR3 | c.255C>T p.I85= | Silent (SNP) | VAF 48/180 reads (27%) | catalogued as COSV59203863; called by muse, mutect2
- TERT | c.1200C>T p.H400= | Silent (SNP) | VAF 66/229 reads (29%) | catalogued as rs755523267, COSV57231285; called by muse, mutect2, varscan2
- TERT | c.801C>T p.D267= | Silent (SNP) | VAF 105/312 reads (34%) | called by muse, mutect2, varscan2
- TRPV5 | c.1468C>T p.L490= | Silent (SNP) | VAF 51/238 reads (21%) | called by muse, mutect2, varscan2
- UBXN4 | c.402A>T p.P134= | Silent (SNP) | VAF 51/171 reads (30%) | called by muse, mutect2, varscan2
- USP36 | c.3090C>G p.L1030= | Silent (SNP) | VAF 61/217 reads (28%) | catalogued as rs763957544; called by muse, mutect2, varscan2
- C12orf45 | chr12:104986286 del TCTCCCCGCCCCCTTACCCGAGCCTTTTTCCTGCAT | 5'UTR (DEL) | VAF 59/262 reads (23%) | called by mutect2, pindel
- CCDC65 | chr12:48923962 C>A | 3'Flank (SNP) | VAF 78/267 reads (29%) | called by muse, mutect2, varscan2
- EIF4E | c.-37C>G | 5'UTR (SNP) | VAF 6/18 reads (33%) | catalogued as rs771465280, COSV99794943; called by muse, mutect2, varscan2
- ENOSF1 | chr18:671325 T>C | 3'Flank (SNP) | VAF 36/133 reads (27%) | called by muse, mutect2, varscan2
- EYS | c.1767-8097C>A | Intron (SNP) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- GALNT14 | c.129+59017C>A | Intron (SNP) | VAF 35/152 reads (23%) | called by muse, mutect2, varscan2
- GSTM1 | c.-14C>T | 5'UTR (SNP) | VAF 155/298 reads (52%) | called by muse, mutect2, varscan2
- HNRNPK | c.1361+360A>T | Intron (SNP) | VAF 52/173 reads (30%) | called by muse, mutect2, varscan2
- MIR514A1 | n.82A>G | RNA (SNP) | VAF 55/554 reads (10%) | called by muse, mutect2, varscan2
- MSC-AS1 | n.447C>G | RNA (SNP) | VAF 67/297 reads (23%) | called by muse, mutect2, varscan2
- PARVB | c.112+15389G>A | Intron (SNP) | VAF 24/99 reads (24%) | called by muse, mutect2, varscan2
- SV2C | c.581-20865C>A | Intron (SNP) | VAF 112/488 reads (23%) | catalogued as COSV59215948; called by muse, mutect2, varscan2
- TSC22D1 | c.*648A>G | 3'UTR (SNP) | VAF 94/281 reads (33%) | catalogued as rs886363663; called by muse, mutect2, varscan2
- TSPAN5 | c.279+12A>T | Intron (SNP) | VAF 30/141 reads (21%) | called by muse, varscan2
